Somatic mutation profile of tumor specimen 0DT3UD from CCDI case PBCIJU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Mesenchymal chondrosarcoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,401 days).
Specimen 0DT3UD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84e73d23-8359-46c8-9de9-b0b4d6d773f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT3UQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e90d928e-2bbb-4f31-a09e-cb79695660a2

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB2 | c.2815G>A p.G939S | Missense Mutation (SNP) | VAF 30/712 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1165585659; called by muse, mutect2
- AMER3 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1290116801; called by muse, mutect2, varscan2
- PCDHA4 | c.2286G>T p.E762D | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as COSV63546772; called by muse, mutect2
- SHLD2 | c.611A>G p.H204R | Missense Mutation (SNP) | VAF 162/459 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1458605923; called by muse, mutect2, varscan2
- DHX33 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARSA | c.618C>T p.F206= | Silent (SNP) | VAF 134/375 reads (36%) | catalogued as rs370296376, COSV53350741; ClinVar: likely benign; called by muse, mutect2, varscan2
- RXRA | c.*90T>G | 3'UTR (SNP) | VAF 69/211 reads (33%) | called by muse, mutect2, varscan2
- TLE6 | c.702+16G>A | Intron (SNP) | VAF 118/342 reads (35%) | catalogued as rs761169221; called by muse, mutect2
